Gene-level copy-number profile of tumor specimen TCGA-A2-A0CL-01A from TCGA case TCGA-A2-A0CL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 37.1 years (13,556 days).
Specimen TCGA-A2-A0CL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.ffc153c8-b303-4bf6-aa6a-9db6f698a9fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0CL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2eed8c1e-6746-4980-900a-c1f1ff8ae4bd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 21,998; copy number 2: 33,013; copy number 3: 1,811; copy number 4: 2,028; copy number 5: 225; copy number 6: 129; copy number 7: 175; copy number 8: 66; copy number 10: 31; copy number 11: 66; copy number 12: 85; copy number 13: 8; copy number 14: 54; copy number 16: 32; copy number 18: 38; copy number 22: 16; copy number 25: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0CL-01A-11D-A111-01): tumor purity 0.14, ploidy 3.47, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,197,446–22,482,959, 1 gene (within-gene range 0–2): AC244502.1.
- chr14:22,265,749–22,479,582, 24 genes: TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 937 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:137,771,660–140,577,397, 55 genes, copy number 6–12 (within-gene range 1–12): LINC01210, AC007159.1, HSPA8P9, CLDN18, AC016252.1, DZIP1L, KRT8P36, A4GNT, AC023049.1, DBR1, ARMC8, NME9, MRAS, ESYT3, AC022497.1, CEP70, FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A, MRPS22, PRR23B, PRR23C, RPL7L1P7, BPESC1, PISRT1, AC119740.1, AC024933.2, AC024933.1, COPB2, U6, AC046134.2, RBP2, AC097103.1, ACTG1P1, RBP1, NMNAT3, AC046134.1, RN7SKP124, RN7SL724P, AC110716.2, AC110716.1, AC016933.1, TRMT112P5, CLSTN2, AC010181.1, AC010181.2, CLSTN2-AS1.
- chr3:141,228,726–144,048,719, 62 genes, copy number 6–10 (broad region; genes not listed).
- chr3:149,761,100–149,968,385, 1 gene, copy number 5 (within-gene range 2–5): ANKUB1.
- chr3:149,812,770–152,465,780, 59 genes, copy number 5–12 (within-gene range 1–12): RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24, AC117386.2, AC022494.1, LINC01998, RPL32P9, AC117386.1, LINC01213, U2, LINC01214, AC018545.1, TSC22D2, SERP1, EIF2A, SELENOT, AC069236.1, ERICH6, ERICH6-AS1, SNRPCP3, AC011317.1, SIAH2, SIAH2-AS1, CLRN1-AS1, MINDY4B, AC020636.2, AC020636.1, CLRN1, AC108726.1, MED12L, RNA5SP145, GPR171, P2RY14, SETP11, AC078816.1, GPR87, P2RY13, P2RY12, IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066, AADACL2, AADACL2-AS1, AC068647.1, AADACP1, AC068647.2, AADAC, SUCNR1, AC108718.1, MBNL1, MBNL1-AS1, TMEM14EP.
- chr4:108,407,843–108,678,874, 8 genes, copy number 5: RPSAP34, ZACNP1, EXOC7P1, RPL34-DT, RPL34, OSTC, RNU6-431P, AC107071.1.
- chr4:113,900,284–117,085,576, 28 genes, copy number 5–8 (within-gene range 2–8): ARSJ, AC104779.1, AC093815.1, UGT8, MIR577, CIR1P2, RN7SL808P, NDST4, MRPS33P3, RPF2P2, PGAM4P2, KRT18P21, AC027613.1, EIF3KP3, TTC39CP1, MTRNR2L13, MIR1973, TRMT112P1, CUL4AP1, AC106892.1, ACTN4P1, AC093765.5, AC093765.4, AC093765.3, AC093765.2, RNU6-119P, AC093765.1, TRAM1L1.
- chr4:119,494,397–120,066,858, 9 genes, copy number 5 (within-gene range 2–5): PDE5A, AC080089.1, AC080089.2, LINC01365, AC097173.1, LINC02502, Y_RNA, AC097173.2, MAD2L1.
- chr4:120,091,046–120,092,282, 1 gene, copy number 5: LTV1P1.
- chr4:123,490,242–124,712,732, 14 genes, copy number 5: AC093821.1, LINC02435, LINC01091, AC096732.1, RPL21P50, AC093767.1, AC108075.1, PPIAP76, AC121154.1, AC133530.1, TUBAP10, TECRP2, LINC02516, ANKRD50.
- chr5:23,951,348–25,445,925, 28 genes, copy number 5: C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2.
- chr7:11,370,365–11,832,198, 1 gene, copy number 5 (within-gene range 2–5): THSD7A.
- chr7:11,820,317–11,821,294, 1 gene, copy number 5: THRAP3P3.
- chr7:15,200,317–24,981,634, 140 genes, copy number 5–18 (broad region; genes not listed).
- chr7:158,532,718–159,233,377, 14 genes, copy number 5: MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr10:59,551,404–63,658,521, 48 genes, copy number 16–22: MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1.
- chr10:71,396,920–71,815,947, 1 gene, copy number 7 (within-gene range 3–7): CDH23.
- chr10:71,711,701–71,851,325, 4 genes, copy number 7 (within-gene range 4–7): C10orf105, VSIR, MIR7152, PSAP.
- chr10:77,730,766–77,926,755, 8 genes, copy number 11 (within-gene range 2–11): AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P.
- chr10:79,860,573–84,561,263, 70 genes, copy number 7–18 (broad region; genes not listed).
- chr10:99,329,356–100,667,009, 42 genes, copy number 11: CNNM1, GOT1, AL391684.1, LINC01475, AL513542.1, NKX2-3, SLC25A28, AL353719.1, AL133353.1, AL133353.2, ENTPD7, EBAG9P1, CUTC, COX15, ABCC2, NANOGP6, DNMBP, DNMBP-AS1, CPN1, CYP2C23P, TPM4P1, SPCS2P2, ERLIN1, CHUK, AL138921.2, AL138921.1, CWF19L1, SNORA12, PHBP9, RNU6-422P, BLOC1S2, PKD2L1, AL139819.1, SCD, OLMALINC, Y_RNA, WNT8B, SEC31B, AL133352.1, NDUFB8, HIF1AN, Metazoa_SRP.
- chr10:120,759,898–121,975,217, 20 genes, copy number 13–25: WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2.
- chr11:45,095,806–47,269,033, 68 genes, copy number 6 (broad region; genes not listed).
- chr11:47,270,657–47,272,110, 1 gene, copy number 6: MADD-AS1.
- chr11:76,654,169–80,653,988, 68 genes, copy number 5–7 (broad region; genes not listed).
- chr11:92,161,106–92,896,470, 7 genes, copy number 7 (within-gene range 1–7): RPL7AP57, NDUFB11P1, FAT3, PGAM1P9, AP000722.1, RPS3AP42, AP003718.1.
- chr16:53,598,153–57,148,369, 92 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr16:61,055,399–62,037,035, 5 genes, copy number 5 (within-gene range 2–5): RPS27AP16, AC092125.2, CDH8, AC092125.1, RN7SKP76.
- chr20:4,192,932–6,220,759, 58 genes, copy number 7–11: LINC01433, ADRA1D, AL139350.1, AL121781.1, AL121916.1, RPS4XP2, PRNP, PRND, PRNT, IDI1P3, AL133396.1, RASSF2, SLC23A2, AL389886.1, AL121890.1, AL121890.3, AL121890.2, AL121890.5, AL121890.4, TMEM230, RNA5SP474, Y_RNA, PCNA, AL121924.1, CDS2, UBE2D3P1, PROKR2, AL121757.2, RNA5-8SP7, AL121757.3, LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1, RNU1-55P, CHGB, KANK1P1, TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3.
- chr20:55,997,357–56,786,087, 24 genes, copy number 5: CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P.

Autosomal genes at a single copy (total copy number 1): 20,866. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
